Surgical pathology report (de-identified scan), TCGA case TCGA-44-6774, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6774-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Level 11 node
- B. Level 9 node
- C. Level 8 node
- D. Level 7 node
- E. Level 5 node
- F. Left lower lobe

CLINICAL NOTES

--

GROSS DESCRIPTION

- A. [The specimen is] Received unfixed labeled "level 11 node" and consists of two pieces of black soft tissue measuring 1.5 cm. in greatest aggregate dimension. AS-1.
- B. Received unfixed labeled "level 9 node" and consists of a piece of black soft tissue measuring 0.5 cm. in greatest dimension. AS-1.
- C. Received unfixed labeled "level 8 node" and consists of a piece of red and black soft tissue measuring 1.6 cm. in greatest dimension. AS-1.
- D. Received unfixed labeled "level 7 node" and consists of two pieces of gray soft tissue measuring 1.6 x 1.5 x 0.3 cm. in aggregate. AS-1.
- E. Received unfixed labeled "level 5 node" and consists of three pieces of red and black soft tissue measuring 2 cm. in greatest aggregate dimension. AS-1. [REDACTED]: [REDACTED]

F. The specimen is received unfixed labeled "left lower lobe" and consists of a 193 gram lung lobe measuring 17 x 11.5 x 3.5 cm. At the narrow and probable and superior edge of the specimen there is an area that is firm by palpation that measures 3 cm. in greatest dimension on external palpation. There is some slight puckering of the pleural surface in this area. Additional sections after fixation. Portion of the specimen is taken for research purposes. [REDACTED]: [REDACTED]

Block summary: 1 - bronchial margin; 2 - next level of bronchus; 3-6 tumor with adjacent stapled margin; 7,8 non-tumorous lung.

[REDACTED]: [REDACTED]

MICROSCOPIC DESCRIPTION

- A. There is no evidence of malignancy in any of 3 lymph nodes pieces.
- B. There is no evidence of malignancy in a single lymph node piece.
- C. There is no evidence of malignancy in any of 5 lymph nodes pieces.
- D. Metastatic carcinoma is present in one of 2 lymph nodes. The metastasis measures 1.8 mm in greatest dimension. No extranodal tumor is seen.

[page 2 of 2]
[REDACTED]

E. There is no evidence of malignancy in any of 3 lymph nodes.
F.

Tumor type: Adenocarcinoma
Tumor grade: 2-3 of 3
Mitotic Index: 24 mitoses/10 HPFs (1 HPF = 0.19 sq mm)
Tumor size: 2 cm
Bronchial resection margin: Negative for malignancy
Pulmonary margin of resection: Negative for malignancy
Pleura: Negative for malignancy
Vascular invasion: Absent
Attached lymph nodes: None
pTNM Stage: T1 N2
Non-tumorous lung: Focal endogenous lipoid pneumonia

3x5,4

DIAGNOSIS

- A. Lymph node, level XI, biopsy:
There is no evidence of malignancy in any of 3 lymph nodes
pieces
- B. Lymph node, level IX biopsy:
A single lymph node is negative for malignancy
- C. Lymph node, level VIII, biopsy:
There is no evidence of malignancy in any of 5 lymph nodes
pieces
- D. Lymph node, level VII, biopsy:
Metastatic carcinoma is present in one of 2 lymph nodes
- E. Lymph node, level V, biopsy:
There is no evidence of malignancy in any of 3 lymph nodes
- F. Lung, left lower lobe, resection:
Moderately to poorly differentiated adenocarcinoma

[REDACTED] : [REDACTED] ----- [REDACTED]
[REDACTED] (Electro [REDACTED] ature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 59fd57a0-27c6-462a-9daa-eddc85818017 (TCGA-44-6774.F9587269-4F32-497A-A95A-42D505AF2434.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).